Somatic mutation profile of tumor specimen ALCH-ADXY-TTP1-A (aliquot ALCH-ADXY-TTP1-A-1-0-D-A603-36) from ALCHEMIST case ALCH-ADXY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.4 years (24,614 days).
Specimen ALCH-ADXY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 638619a6-bf98-46c9-b9a2-a99560ed32a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADXY-NB1-A (Blood Derived Normal), aliquot ALCH-ADXY-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b2cd667-47ac-4f36-ae86-2ce1d02fa170

The open-access MAF lists 31 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 3, RNA 2, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 62/166 reads (37%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.150+1G>A p.X50_splice | Splice Site (SNP) | VAF 31/260 reads (12%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2, varscan2
- FOLR3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs1287584454, COSV61529960; called by muse, mutect2
- GOLGA6D | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as rs768819783, COSV101461821; called by muse, mutect2, varscan2
- HIPK3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs376939727, COSV57561140; called by muse, mutect2, varscan2
- OR11H1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 86/1272 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs202196153, COSV53272610; called by muse, mutect2
- OTOG | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs926211867; called by muse, mutect2, varscan2
- PRPF6 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53865504; called by muse, mutect2, varscan2
- SEC16B | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 61/250 reads (24%) | catalogued as rs763978372; called by muse, mutect2, varscan2
- SPATA17 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs768392685, COSV65125514; called by muse, mutect2, varscan2
- ADAM23 | c.1967T>A p.F656Y | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- EXO1 | c.1096A>T p.N366Y | Missense Mutation (SNP) | VAF 112/454 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OLA1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2
- OR10H3 | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 102/389 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RAB11FIP1 | c.2184_2185insTA p.A729* | Frame Shift Ins (INS) | VAF 44/259 reads (17%) | called by mutect2, pindel, varscan2
- SEMA3D | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- SLC6A5 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- TSSK2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VEZF1 | c.929A>T p.Q310L | Missense Mutation (SNP) | VAF 58/612 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ZNF560 | c.2132C>A p.P711H | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS16 | c.3660T>C p.S1220= | Silent (SNP) | VAF 43/430 reads (10%) | catalogued as rs774125500; called by muse, mutect2, varscan2
- LEP | c.42C>T p.P14= | Silent (SNP) | VAF 126/497 reads (25%) | catalogued as COSV100451467; called by muse, mutect2, varscan2
- MYT1L | c.705C>T p.D235= | Silent (SNP) | VAF 117/570 reads (21%) | catalogued as rs773102100, COSV67707140; called by muse, mutect2, varscan2
- SGMS2 | c.1002C>T p.S334= | Silent (SNP) | VAF 179/749 reads (24%) | called by muse, mutect2, varscan2
- SHROOM2 | c.3969C>T p.I1323= | Silent (SNP) | VAF 10/250 reads (4%) | catalogued as rs1308167839, COSV66604993; called by muse, mutect2
- WNK1 | c.6948C>T p.F2316= (on ENST00000315939 / NM_018979.4; = p.F2068= on NM_014823.3) | Silent (SNP) | VAF 51/702 reads (7%) | called by muse, mutect2
- ABCC4 | c.75-21601T>C | Intron (SNP) | VAF 53/333 reads (16%) | called by muse, mutect2, varscan2
- AC025048.6 | n.241C>T | RNA (SNP) | VAF 18/314 reads (6%) | catalogued as rs1489325279; called by muse, mutect2
- PCMTD1 | c.-360G>A | 5'UTR (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- TMEM99 | n.740G>A | RNA (SNP) | VAF 9/245 reads (4%) | called by muse, mutect2
- VRK3 | chr19:49972068 T>G | 3'Flank (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
